Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RQ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RQ-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Oligodendroglioma, grade II
9450/3

CCCF
Site Brain, supratentorial NOS
C71.0

Path

Brain, temporal lobe
C71.2

Nature of material: Brain

Received on:

Macroscopy:

8/10/13

Received in formalin 2 fragments of brain parenchyma, weighing 16.0 g and measuring together 4.5 x 3.5 x 1.5 cm. Present congested and brown-blackish outer surface. To the cuts, there is whitish and homogeneous aspect.

Microscopy:

Histological sections stained with H & E show fragments of neuroepithelial tumor composed of cells of round nuclei, delicate chromatin and inconspicuous nucleoli. The cytoplasm is scant with imprecise limits. Neoplastic cells are arranged on a fibrillar background sometimes forming microcysts and diffusely infiltrating the cerebral cortex, where it is observed conspicuous neuron satellitosis by neoplastic cells. It is noted the few areas with increased cellularity, wherein the cancer cells have a higher degree of atypia and occasional mitotic figures (2-3 mitoses per 10 high-power fields). It also demonstrates the formation of secondary Scherer structures in the subpial region and around some blood vessels. There are no areas of necrosis or microvascular proliferation in this material.

Diagnosis:

Excisional biopsy product of lesion in left temporal lobe:

- Oligodendroglioma with focal areas of anaplasia (grade II / III WHO, ICD-O 9450/3).

PROFESSIONAL PARTICIPANTS OF REPORT

Pw TSS, dx discrepancy
form, TCGA tumor is
a grade II. BCR.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Brain lower grade glioma - (Brain Lower Grade Glioma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	F

Tumor Identifier Provided on Initial Case Quality Control Form	Provide the tumor identifier documented on the initial case quality control form for this case.	
Pathologic Diagnosis Provided on Initial Pathology Report	Oligodendroglioma III	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
Histologic features of the sample provided for TCGA, as reflected on the QCFC	Oligodendroglioma II	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.
Discrepancy between Pathology Report and Case Quality Control Form		
Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form	wrote "The initial diagnosis was more descriptive regarding the grade. The area of anaplasia is very focal and the ki-67 LI is < 5% in that area. Also the overwhelming of the tumor is low-grade, including the sample was sent to TCGA"	
Name of TSS Reviewing Pathologist or Biorepository Director	Provide the name of the pathologist who reviewed this case for TCGA.	

Source: NCI Genomic Data Commons file e9f2852e-7144-4bf0-87d1-52f12b7bf974 (TCGA-TQ-A7RQ.627A2B25-6FC6-4CF3-9EA8-D9159B49B205.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).